Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040028-04A.2 (aliquot TARGET-15-SJMPAL040028-04A.2-01D) from TARGET case TARGET-15-SJMPAL040028, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.2 years (6,265 days).
Specimen TARGET-15-SJMPAL040028-04A.2: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50434e2b-2969-401d-af2b-73959ae28ab7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040028-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040028-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49e10478-f1b0-4a0f-a72e-8a2c4a612fa6

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 4, Silent 3, RNA 2, Frame Shift Ins 1, Splice Region 1, 5'UTR 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15210T>A p.Y5070* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV56491819; called by muse, mutect2, varscan2
- MYCN | c.134dup p.E47Gfs*8 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | catalogued as rs780080562; called by mutect2, varscan2
- ZNF608 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200298192, COSV60437581; called by muse, mutect2, varscan2
- AQP3 | c.136G>T p.V46F | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.239); called by muse, mutect2
- FBXL18 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FNDC11 | c.250C>A p.H84N | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2
- NEU1 | c.1021+4_1021+7del | Splice Region (DEL) | VAF 30/83 reads (36%) | called by mutect2, varscan2
- NR3C1 | c.638G>T p.W213L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2
- RNF11 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SMARCA4 | c.1684G>C p.A562P | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); called by muse, varscan2
- ZNF304 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- EFTUD2 | c.1212G>A p.T404= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs200389815; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPHP4 | c.564G>T p.T188= | Silent (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- PPP1R26 | c.1509C>T p.D503= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs377344013; called by muse, mutect2
- AC073343.1 | n.644C>A | RNA (SNP) | VAF 3/24 reads (13%) | catalogued as rs1383414101; called by muse, mutect2
- CCDC90B | c.100+16G>T | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- FAM120AOS | c.564-544G>T | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- ITFG2 | c.406+9G>T | Intron (SNP) | VAF 19/46 reads (41%) | catalogued as COSV57390913; called by muse, varscan2
- NPC1L1 | c.-6_-5insT | 5'UTR (INS) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- PLEKHM1 | c.*1621G>T | 3'UTR (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- SUPT3H | c.946-36G>T | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- TUBA5P | n.183G>T | RNA (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
